Somatic mutation profile of tumor specimen 0DV7GY from CCDI case PBCLSC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Malignant tumor, spindle cell type; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 0.1 years (34 days).
Specimen 0DV7GY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 56882cd2-f283-46ee-b82b-d8dea0f920fb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DV7GV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f57de59-884e-4135-91ef-9fafd029b744

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VAV2 | c.2339G>A p.R780Q (on ENST00000371850 / NM_001134398.2; = p.R770Q on NM_003371.4) | Missense Mutation (SNP) | VAF 114/341 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs767880414, COSV64085047; called by muse, mutect2, varscan2
- SPAG16 | c.*15C>T | 3'UTR (SNP) | VAF 437/869 reads (50%) | catalogued as COSV100435360; called by muse, mutect2, varscan2
